Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17M, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17M-01A (Primary Tumor).

[page 1 of 5]
8380/3 12/9/10

Site Code: Endometrium C54.1 ^{pw}

Surgical Pathology

DIAGNOSIS:

A. Uterus, hysterectomy: Endometrial adenocarcinoma, endometrioid type, FIGO grade 1 (of 3) is identified forming a mass (4.7 x 3.9 x 1.9 cm) circumferentially involving the endometrial cavity. The tumor invades 0.5 cm into the myometrium (total myometrial thickness, 2.1 cm). A separate nodule of invasive adenocarcinoma is seen in the superficial endocervical canal. The ectocervical margin is negative by 1.5 cm. Lymphovascular space invasion is not identified. [AJCC pT 2a N0 M0].

B. Ovary and fallopian tube, right, salpingo-oophorectomy: Without diagnostic abnormality. Frozen section histologic interpretation performed by:

C. Ovary and fallopian tube, left, salpingo-oophorectomy: Without diagnostic abnormality. Frozen section histologic interpretation performed by:

D. Lymph nodes, right pelvic, biopsy: Multiple (8) right pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

E. Lymph nodes, left pelvic, biopsy: Multiple (5) left pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

F. Lymph nodes, left pelvic, biopsy: Multiple (2) left pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

[page 2 of 5]
This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s). Revision based on review of H&E permanent section(s).

AMENDMENTS: (Previous Signout Date:)
Revision Description: Case was inappropriately staged at time of frozen section.

....Original Diagnosis....

A. Uterus, hysterectomy: Endometrial adenocarcinoma, endometrioid type, FIGO grade 1 (of 3) is identified forming a mass (4.7 x 3.9 x 1.9 cm) circumferentially involving the endometrial cavity. The tumor invades 0.5 cm into the myometrium (total myometrial thickness, 2.1 cm). A separate nodule of invasive adenocarcinoma is seen in the superficial endocervical canal. The ectocervical margin is negative by 1.5 cm. Lymphovascular space invasion is not identified. [AJCC pT1b N0 M0].

B. Ovary and fallopian tube, right, salpingo-oophorectomy: Without diagnostic abnormality. Frozen section histologic interpretation performed by:

C. Ovary and fallopian tube, left, salpingo-oophorectomy: Without diagnostic abnormality. Frozen section histologic interpretation performed by:

D. Lymph nodes, right pelvic, biopsy: Multiple (8) right pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

[page 3 of 5]
E. Lymph nodes, left pelvic, biopsy: Multiple (5) left pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

F. Lymph nodes, left pelvic, biopsy: Multiple (2) left pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is a 160.0 gram uterus with attached cervix. The uterine serosa has focal fibrous adhesions. There is a 4.7 x 3.9 x 1.9 cm mass circumferentially involving the endometrium with a 2.1 cm myometrial thickness. There are no leiomyomas. A separate 0.7 cm nodule is seen in the endocervical canal, 1.5 cm from the endocervical margin. Representative sections are submitted.

B. Received fresh labeled "right fallopian tube and ovary" is a 2.1 x 1.4 x 1.0 cm ovary with a 2.9 x 0.9 cm attached fallopian tube. The ovary has a smooth outer surface and a solid cut surface. Representative sections submitted.

C. Received fresh labeled "left fallopian tube and ovary" is a 2.2

[page 4 of 5]
x 1.4 x 1.1 cm ovary with a 4.2 x 0.8 cm attached fallopian tube.

The ovary has a smooth outer surface and a solid cut surface.

Representative sections submitted.

D. Received fresh labeled "right pelvic lymph nodes" is a 7.4 x 6.9

x 1.7 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "left pelvic lymph nodes" is a 4.5 x 4.5

x 1.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

F. Received fresh labeled "additional left pelvic lymph nodes" is a

1.1 x 1.0 x 0.9 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus

- 1 Cervix
- 2 Lower uterine segment
- 3 Endometrium mass 1
- 4 Endometrium mass 2
- 5 Myometrium full thickness
- 6 Endometrium full thickness
- 7 Posterior uterine serosa
- 8 Cervix 12:00

Part B: Right fallopian tube and ovary

- 1 Rt ovary
- 2 Rt fallopian tube

Part C: Left fallopian tube and ovary

- 1 Lt ovary
- 2 Lt fallopian tube

Part D: Right Pelvic Lymph Nodes

- 1 Right pelvic lns 4 (D1)
- 2 Rt pelvic lns 1 of 2 (D2)
- 3 Rt pelvic lns 2 of 2 (D2)
- 4 Right pelvic lns 3 (D3)
- 5 Right pelvic lns 2 (D4)

[page 5 of 5]
6 Right pelvic lns 1 (D5)

Part E: Left Pelvic Lymph Nodes

- 1 Left pelvic lns 1 (E1)
- 2 Left pelvic lns 3 (E2)
- 3 Left pelvic lns 1 (E3)

Part F: Additional left pelvic lymph nodes

- 1 Additiona Lt pelvic LN 2 (F1)
- 2 Additional Lt pelvic LN 1 (F2)

Source: NCI Genomic Data Commons file 8647a174-c340-4807-a7e1-ac8b59bbad8e (TCGA-D1-A17M.E69EF984-AF58-4EB0-93D2-CADE53DF0A6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).